Somatic mutation profile of tumor specimen 0DQS04 from CCDI case PBCFGZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,206 days).
Specimen 0DQS04: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5538471d-d38c-4091-8d97-282cb2557cac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQS0L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98b1ce5d-5e6c-47f1-83a9-fc6c8b3ed977

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.16249G>A p.V5417I | Missense Mutation (SNP) | VAF 77/1866 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs375876245; called by muse, mutect2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 12/126 reads (10%) | catalogued as rs1262556378; called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 17/364 reads (5%) | called by muse, mutect2
